Somatic mutation profile of tumor specimen 0DQHAZ from CCDI case PBCEVR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 13.4 years (4,885 days).
Specimen 0DQHAZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6a46eb5-3bc6-486b-98a1-2a7a078d0614.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQHAE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d8d8dcf-52ec-4bd2-ba68-607713ec7625

The open-access MAF lists 46 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, Intron 5, Nonsense Mutation 3, 3'UTR 2, Frame Shift Ins 2, Splice Site 1, 5'Flank 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOA2 | c.258C>A p.F86L | Missense Mutation (SNP) | VAF 187/1242 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.019); catalogued as COSV99248074; called by muse, mutect2, varscan2
- CAPN12 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 99/957 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1190490294; called by muse, mutect2, varscan2
- COBLL1 | c.758C>T p.A253V (on ENST00000392717; = p.A215V on NM_014900.5) | Missense Mutation (SNP) | VAF 274/1110 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs764256858; called by muse, mutect2, varscan2
- CTR9 | c.2491G>A p.A831T | Missense Mutation (SNP) | VAF 316/1136 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1468838652; called by muse, mutect2, varscan2
- CYP11B2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 346/1122 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs369953763; called by muse, varscan2
- FAM171A1 | c.2561G>A p.R854K | Missense Mutation (SNP) | VAF 25/550 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0.084); catalogued as COSV65317891; called by muse, mutect2
- FBXO30 | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 227/1129 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1228295014, COSV52791674; called by muse, mutect2, varscan2
- HCAR1 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 190/1144 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV100811826, COSV63677838; called by muse, mutect2, varscan2
- LMLN2 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 208/1008 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.049); catalogued as rs1015404657; called by muse, mutect2, varscan2
- POLR1B | c.1739A>G p.H580R | Missense Mutation (SNP) | VAF 165/529 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs745372133; called by muse, mutect2, varscan2
- RNF128 | c.31dup p.W11Lfs*11 | Frame Shift Ins (INS) | VAF 256/604 reads (42%) | catalogued as rs757038390; called by mutect2, varscan2
- SLC17A6 | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 308/1067 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV54134971; called by muse, mutect2, varscan2
- TASOR2 | c.6374G>A p.S2125N | Missense Mutation (SNP) | VAF 54/925 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV60169325; called by muse, mutect2
- TIGAR | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 231/1383 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1366686598; called by muse, mutect2, varscan2
- TTN | c.38648A>G p.N12883S (on ENST00000591111; = p.N5459S on NM_003319.4) | Missense Mutation (SNP) | VAF 320/1129 reads (28%) | PolyPhen possibly damaging (0.737); catalogued as COSV60359611; called by muse, mutect2, varscan2
- ASMTL | c.1498G>C p.A500P | Missense Mutation (SNP) | VAF 53/1660 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- ASXL3 | c.2082dup p.M695Yfs*9 | Frame Shift Ins (INS) | VAF 342/1474 reads (23%) | called by mutect2, varscan2
- CCDC66 | c.1800T>A p.Y600* (on ENST00000394672 / NM_001353147.1; = p.Y566* on NM_001012506.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 386/1372 reads (28%) | called by muse, mutect2, varscan2
- CLP1 | c.929G>A p.G310D | Missense Mutation (SNP) | VAF 154/658 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- DOCK3 | c.1685A>G p.Y562C | Missense Mutation (SNP) | VAF 453/1047 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCTD17 | c.141G>C p.Q47H | Missense Mutation (SNP) | VAF 72/342 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- LMO7 | c.4881+1G>C p.X1627_splice (on ENST00000357063; = p.X1308_splice on NM_005358.5) | Splice Site (SNP) | VAF 327/1427 reads (23%) | called by muse, mutect2, varscan2
- LYAR | c.1078A>T p.K360* | Nonsense Mutation (SNP) | VAF 232/1302 reads (18%) | called by muse, mutect2, varscan2
- MAN1C1 | c.590A>C p.N197T | Missense Mutation (SNP) | VAF 158/1344 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PPP4R1 | c.2233C>T p.Q745* (on ENST00000400556 / NM_001042388.3; = p.Q728* on NM_005134.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 186/1019 reads (18%) | called by muse, mutect2, varscan2
- ROCK2 | c.3620A>C p.H1207P | Missense Mutation (SNP) | VAF 297/1019 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TG | c.6236T>C p.V2079A | Missense Mutation (SNP) | VAF 236/843 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADH5 | c.744A>G p.K248= | Silent (SNP) | VAF 263/1305 reads (20%) | called by muse, mutect2, varscan2
- BSPH1 | c.24C>T p.F8= | Silent (SNP) | VAF 118/537 reads (22%) | catalogued as rs548885170; called by muse, varscan2
- C10orf105 | c.189G>A p.A63= | Silent (SNP) | VAF 38/1024 reads (4%) | catalogued as rs1048415826; called by muse, mutect2
- CCDC85A | c.912G>A p.T304= | Silent (SNP) | VAF 93/376 reads (25%) | catalogued as rs1001155155, COSV68155624; called by muse, mutect2, varscan2
- COPG2 | c.2211A>G p.G737= | Silent (SNP) | VAF 152/1304 reads (12%) | called by mutect2, varscan2
- DEPP1 | c.120C>T p.Y40= | Silent (SNP) | VAF 80/394 reads (20%) | catalogued as rs201098879; called by muse, mutect2, varscan2
- DLG5 | c.1695G>C p.L565= | Silent (SNP) | VAF 177/888 reads (20%) | called by muse, mutect2, varscan2
- SCPEP1 | c.852G>A p.S284= | Silent (SNP) | VAF 249/1685 reads (15%) | catalogued as rs776942064; called by muse, mutect2, varscan2
- SIPA1L3 | c.3177G>A p.S1059= | Silent (SNP) | VAF 113/814 reads (14%) | catalogued as rs145667425; called by muse, mutect2, varscan2
- ARG2 | c.523-34C>A | Intron (SNP) | VAF 77/633 reads (12%) | catalogued as rs1201533068; called by muse, mutect2, varscan2
- BCAT2 | c.695+33C>T | Intron (SNP) | VAF 106/440 reads (24%) | called by muse, mutect2, varscan2
- EEF2 | c.613-74C>G | Intron (SNP) | VAF 33/248 reads (13%) | called by muse, mutect2, varscan2
- ING1 | chr13:110714121 C>G | 5'Flank (SNP) | VAF 94/440 reads (21%) | catalogued as rs1361439399; called by muse, mutect2, varscan2
- KRTAP4-12 | c.*72C>T | 3'UTR (SNP) | VAF 10/63 reads (16%) | catalogued as rs536748894; called by muse, mutect2, varscan2
- NUDCD1 | c.118+3992T>C | Intron (SNP) | VAF 68/338 reads (20%) | called by muse, mutect2, varscan2
- P2RX6 | c.*194C>T | 3'UTR (SNP) | VAF 25/92 reads (27%) | catalogued as rs529044977, COSV60386355; called by muse, mutect2, varscan2
- RFC4 | c.801+17_801+18insG | Intron (INS) | VAF 400/972 reads (41%) | called by mutect2, varscan2*
- RGS9 | c.-41T>A | 5'UTR (SNP) | VAF 58/349 reads (17%) | called by muse, mutect2, varscan2
- SOX15 | chr17:7583295 G>C | 3'Flank (SNP) | VAF 118/347 reads (34%) | called by muse, mutect2, varscan2
